Somatic mutation profile of tumor specimen TARGET-10-PASNEH-09A (aliquot TARGET-10-PASNEH-09A-01D) from TARGET case TARGET-10-PASNEH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,167 days).
Specimen TARGET-10-PASNEH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 902e0bbe-f6a4-40e6-8c3c-fd68ea90bd62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASNEH-10A (Blood Derived Normal), aliquot TARGET-10-PASNEH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96bdc67b-9fd5-4270-ad1e-ccfed1f40064

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HAVCR2 | c.355A>T p.N119Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57154041; called by muse, mutect2, varscan2
- KIF21B | c.4481G>A p.G1494D (on ENST00000422435 / NM_001252100.2; = p.G1481D on NM_017596.4) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV59762546; called by muse, mutect2, varscan2
- NOTCH1 | c.4817_4818insAAC p.F1606delinsLT | In Frame Ins (INS) | VAF 23/54 reads (43%) | catalogued as COSV53027782, COSV53042984, COSV53043409, COSV53046232, COSV53074253, COSV53074374, COSV53075070, COSV53075246, COSV53075642, COSV53081693, COSV53092183, COSV53095779, COSV53096923, COSV53096963, COSV53097268, COSV5…; called by mutect2, pindel, varscan2
- RAD21 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057524012, COSV52057638, COSV52062783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLOD4 | c.675+35A>C | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
